Somatic mutation profile of tumor specimen TCGA-85-8052-01A (aliquot TCGA-85-8052-01A-11D-2244-08) from TCGA case TCGA-85-8052, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.9 years (19,671 days).
Specimen TCGA-85-8052-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43c44208-7fe8-4ada-9bf1-80f573ded429.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8052-10A (Blood Derived Normal), aliquot TCGA-85-8052-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af3e9f3d-3289-45e7-9672-7f1f68014d0b

The open-access MAF lists 138 somatic variants for this specimen: 100 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 34, Frame Shift Del 7, Nonsense Mutation 4, Splice Site 2, 3'Flank 1, 5'UTR 1, Intron 1, Frame Shift Ins 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs999380946, CM140945; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.2656G>C p.A886P | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV101275975; called by muse, mutect2, varscan2
- ABCC12 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV60918027; called by muse, mutect2, varscan2
- ACSM2A | c.1427C>A p.S476* (on ENST00000219054; = p.S397* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV54585974, COSV99524758; called by muse, mutect2, varscan2
- CACNA1B | c.505A>C p.M169L | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.945); catalogued as COSV99498552; called by muse, mutect2, varscan2
- CCDC158 | c.1138del p.Q380Kfs*14 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as COSV101187130; called by mutect2, pindel, varscan2
- CCDC69 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs142070600; called by muse, mutect2, varscan2
- ERICH3 | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV58614363; called by muse, mutect2, varscan2
- ERICH3 | c.2271G>T p.K757N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV58615069; called by muse, mutect2, varscan2
- ERICH3 | c.1169G>T p.R390I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1238064275; called by muse, mutect2, varscan2
- ERICH6 | c.710C>G p.T237R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55798621; called by muse, mutect2, varscan2
- ETV5 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs1239539716; called by muse, mutect2
- FBXL4 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755008031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAPDH | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.224); catalogued as COSV99975595; called by muse, mutect2
- IGHD6-13 | c.19T>A p.Y7N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as rs535576213; called by muse, mutect2, varscan2
- KCNB2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV73051676; called by muse, mutect2, varscan2
- KCNC2 | c.1208C>A p.A403D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54364357, COSV54375730; called by muse, mutect2
- KMT2D | c.8060del p.R2687Qfs*4 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as COSV56417652; called by mutect2, varscan2
- MBD5 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs767306594, COSV68696730; called by muse, mutect2, varscan2
- MEGF8 | c.7541G>T p.R2514L (on ENST00000251268 / NM_001271938.2; = p.R2447L on NM_001410.3) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs369692848, COSV52088151; called by muse, mutect2, varscan2
- NOS1 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57605801, COSV57605933; called by muse, mutect2, varscan2
- NSUN5 | c.1146-1G>C p.X382_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | catalogued as rs1198833061, COSV99392480; called by muse, mutect2, varscan2
- OR10Z1 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63525783; called by muse, mutect2, varscan2
- PDZD2 | c.5800C>T p.R1934W | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs751086010; called by muse, mutect2
- POT1 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs1197625483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS1 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs1334387532; called by muse, mutect2, varscan2
- RTN1 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867021176, COSV50733073; called by muse, mutect2, varscan2
- SCAF4 | c.1558A>G p.T520A | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs1182972500; called by muse, mutect2, varscan2
- SCUBE2 | c.1091-2A>G p.X364_splice | Splice Site (SNP) | VAF 63/236 reads (27%) | catalogued as COSV100496824; called by muse, mutect2, varscan2
- SENP5 | c.2026A>G p.I676V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs764070923; called by muse, mutect2, varscan2
- SLC26A4 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM165412; called by muse, mutect2, varscan2
- THNSL2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs376146285, COSV100147244; called by muse, mutect2, varscan2
- TIGD2 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as rs370202366; called by muse, mutect2, varscan2
- TNKS2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.148); catalogued as COSV100861131; called by muse, mutect2
- TXNDC16 | c.1634G>T p.S545I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1201100730; called by muse, mutect2, varscan2
- UBN2 | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746848105, COSV56031400, COSV99944221; called by muse, mutect2, varscan2
- VEGFD | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs780418465, COSV52910417; called by muse, mutect2, varscan2
- WWP1 | c.2606G>A p.G869E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041283027; called by muse, mutect2, varscan2
- ZNF44 | c.434C>T p.P145L (on ENST00000356109 / NM_001164276.2; = p.P97L on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV61135203; called by muse, mutect2, varscan2
- ADGRG5 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, varscan2
- ADGRG5 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ADRB3 | c.124del p.A42Pfs*30 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- AKAP4 | c.731G>T p.S244I | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ANKRD42 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARRDC2 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- BBS9 | c.1166A>G p.Q389R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- BIN2 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C1orf87 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC12 | c.83A>C p.K28T (on ENST00000425441 / NM_001277074.1; = p.K41T on NM_144716.5) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CDH8 | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
- COL12A1 | c.8971A>G p.T2991A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRB1 | c.3759A>T p.R1253S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CYP26C1 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DENND4C | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DMXL2 | c.3666C>G p.I1222M | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAJC9 | c.671A>G p.Q224R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- DSG3 | c.843A>C p.L281F | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- DYSF | c.5240A>C p.E1747A | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EIF2AK4 | c.1615A>C p.I539L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXOC2 | c.2647del p.A883Pfs*18 | Frame Shift Del (DEL) | VAF 34/178 reads (19%) | called by mutect2, pindel, varscan2
- FCGBP | c.2662T>C p.Y888H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGR3A | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FFAR4 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMO5 | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GALNT17 | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- GOLGB1 | c.6476T>A p.I2159N | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); called by muse, mutect2
- GRIN2B | c.3737A>G p.K1246R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GRM3 | c.2068T>C p.F690L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCRTR2 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMA1 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRP2 | c.9779A>G p.N3260S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MDGA2 | c.1021G>T p.A341S (on ENST00000399232 / NM_001113498.2; = p.A43S on NM_182830.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMP2 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- OR10A5 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OR1L8 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR52A5 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5T2 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ORC4 | c.1128T>G p.F376L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKHD1 | c.3439G>T p.D1147Y | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PLD5 | c.1497del p.T501Pfs*63 (on ENST00000442594; = p.T439Pfs*63 on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 68/352 reads (19%) | called by mutect2, pindel, varscan2
- PTPRB | c.5594A>G p.Y1865C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRU | c.1299del p.T434Pfs*6 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- RB1 | c.2330del p.P777Lfs*33 | Frame Shift Del (DEL) | VAF 57/160 reads (36%) | called by mutect2, pindel, varscan2
- SLC22A18 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2
- STKLD1 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 73/525 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TAAR6 | c.471G>C p.W157C | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX18 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TMEM132D | c.3065C>G p.P1022R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNR | c.3290A>T p.E1097V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TRIM42 | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRPS1 | c.1994A>G p.E665G (on ENST00000220888 / NM_001330599.2; = p.E678G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRPS1 | c.1330G>T p.E444* (on ENST00000220888 / NM_001330599.2; = p.E457* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- USF3 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP45 | c.2131T>A p.L711I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VEPH1 | c.736A>G p.K246E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VPS13B | c.11983T>A p.Y3995N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ZIC2 | c.1094G>T p.C365F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APLP1 | c.1806G>T p.L602= (on ENST00000221891 / NM_001024807.3; = p.L601= on NM_005166.4) | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- ARL4C | c.27G>A p.S9= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- BCL11B | c.1134G>T p.P378= (on ENST00000357195 / NM_001282237.2; = p.P307= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CD22 | c.2100C>T p.I700= | Silent (SNP) | VAF 10/232 reads (4%) | catalogued as COSV99323491; called by muse, mutect2
- CDH15 | c.2082C>T p.G694= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- CEACAM20 | c.1710G>A p.V570= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- CENPM | c.285G>A p.G95= | Silent (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- COL6A3 | c.7887C>A p.T2629= | Silent (SNP) | VAF 29/320 reads (9%) | called by muse, mutect2
- FNDC3B | c.3339A>G p.S1113= | Silent (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- GNS | c.1518G>T p.R506= | Silent (SNP) | VAF 18/195 reads (9%) | catalogued as rs1000381159, COSV50693892; called by muse, mutect2
- HDGFL3 | c.105C>T p.G35= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs369609546; called by muse, mutect2, varscan2
- IGHG4 | c.147C>T p.G49= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs747838671; called by muse, mutect2
- IQGAP2 | c.681A>G p.K227= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV57181921; called by muse, mutect2
- MYH9 | c.5295C>T p.D1765= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs756456712; called by muse, mutect2, varscan2
- NXN | c.579G>T p.G193= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- OR6B2 | c.699C>A p.G233= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- OR7E24 | c.780C>T p.G260= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- PARPBP | c.1302T>G p.T434= | Silent (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- PKP2 | c.333A>G p.L111= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs1309112416; called by muse, mutect2, varscan2
- POLQ | c.3096A>T p.S1032= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99952042; called by muse, mutect2, varscan2
- RASA1 | c.990T>C p.L330= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.297A>G p.P99= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- SKP1 | c.426A>G p.K142= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV100104566; called by muse, mutect2
- SLC4A10 | c.942G>A p.E314= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1439674040; called by muse, mutect2, varscan2
- SYNE1 | c.14832G>T p.L4944= (on ENST00000367255 / NM_182961.4; = p.L4873= on NM_033071.3) | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as COSV55032122; called by muse, mutect2, varscan2
- TAAR5 | c.210C>T p.N70= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as rs1562186550; called by muse, mutect2, varscan2
- TBX18 | c.921T>C p.T307= | Silent (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- TEX9 | c.579G>A p.Q193= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- TFAP2C | c.1122G>T p.G374= | Silent (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- TLR3 | c.2085T>G p.S695= | Silent (SNP) | VAF 27/244 reads (11%) | called by muse, mutect2, varscan2
- TRPM3 | c.3840C>T p.A1280= (on ENST00000357533 / NM_001366142.2; = p.A1135= on NM_020952.6) | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs916605838, COSV62581546; called by muse, mutect2
- TTN | c.70143T>C p.S23381= (on ENST00000591111; = p.S15957= on NM_003319.4) | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- VN1R4 | c.9C>A p.S3= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs1254026684, COSV100237485; called by muse, mutect2, varscan2
- ZNF606 | c.2091A>G p.A697= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100071944; called by muse, mutect2, varscan2
- CTDSPL | c.426+1543A>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99828866; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876065 A>C | 3'Flank (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- PJVK | c.1_2del | 5'UTR (DEL) | VAF 6/48 reads (13%) | called by pindel, varscan2
- Unknown | chr21:16194613 C>A | IGR (SNP) | VAF 12/33 reads (36%) | catalogued as rs759309440; called by muse, mutect2, varscan2
